Somatic mutation profile of tumor specimen TCGA-AG-A015-01A (aliquot TCGA-AG-A015-01A-01W-A00K-09) from TCGA case TCGA-AG-A015, project TCGA-READ (Rectum Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectum, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 64.3 years (23,496 days).
Specimen TCGA-AG-A015-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 78392c5d-5be2-42c8-b55d-47ad7c21d0a3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AG-A015-10A (Blood Derived Normal), aliquot TCGA-AG-A015-10A-01W-A00K-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/26321b1b-c405-4b33-85bf-aa53a35b44ab

The open-access MAF lists 110 somatic variants for this specimen: 83 protein-altering or splice-affecting, 22 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 69, Silent 22, Nonsense Mutation 8, Frame Shift Del 2, Frame Shift Ins 2, 3'UTR 2, 5'Flank 1, Intron 1, Splice Site 1, Nonstop Mutation 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 20/48 reads (42%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1636C>A p.Q546K | Missense Mutation (SNP) | VAF 21/65 reads (32%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.843); catalogued as rs121913286, COSV55873527, COSV55882350; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCC12 | c.375G>A p.M125I | Missense Mutation (SNP) | VAF 24/69 reads (35%) | SIFT tolerated (0.44); PolyPhen benign (0.03); catalogued as COSV60912581; called by muse, mutect2, varscan2
- ADGRD1 | c.2230G>A p.D744N | Missense Mutation (SNP) | VAF 54/104 reads (52%) | SIFT tolerated (0.08); PolyPhen benign (0.021); catalogued as rs761442572, COSV55452905, COSV55456953; called by muse, mutect2, varscan2
- AHNAK2 | c.12959C>T p.S4320L | Missense Mutation (SNP) | VAF 35/70 reads (50%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.494); catalogued as rs372983305; called by muse, mutect2, varscan2
- APC | c.3856G>T p.E1286* | Nonsense Mutation (SNP) | VAF 116/143 reads (81%) | catalogued as CM940071, COSV57325166, COSV57330894, COSV57378134; called by muse, mutect2, varscan2
- ASCL4 | c.98G>A p.R33Q | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT tolerated (0.29); PolyPhen benign (0.345); catalogued as COSV60816315; called by muse, mutect2
- CARD11 | c.1064G>T p.G355V | Missense Mutation (SNP) | VAF 22/83 reads (27%) | SIFT tolerated (0.34); PolyPhen benign (0.009); catalogued as COSV67800130; called by muse, mutect2, varscan2
- CCZ1 | c.704G>A p.G235E | Missense Mutation (SNP) | VAF 6/86 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1378027431; called by muse, mutect2
- CRISP1 | c.401C>T p.T134M | Missense Mutation (SNP) | VAF 36/364 reads (10%) | SIFT tolerated (0.26); PolyPhen benign (0.062); catalogued as rs139194307; called by muse, mutect2, varscan2
- CXorf58 | c.470G>A p.R157H | Missense Mutation (SNP) | VAF 54/131 reads (41%) | SIFT tolerated (0.62); PolyPhen benign (0.005); catalogued as rs765534922, COSV64858063; called by muse, mutect2, varscan2
- DLX5 | c.691C>T p.R231C | Missense Mutation (SNP) | VAF 4/58 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.924); catalogued as COSV56031768, COSV56033712; called by muse, mutect2
- DRP2 | c.287G>A p.R96H | Missense Mutation (SNP) | VAF 54/119 reads (45%) | SIFT tolerated (0.53); PolyPhen possibly damaging (0.808); catalogued as rs144183424, COSV99063878; called by muse, mutect2, varscan2
- FAM171B | c.2458C>T p.R820C | Missense Mutation (SNP) | VAF 31/92 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as rs148878744; called by muse, mutect2, varscan2
- FAT1 | c.3690A>T p.R1230S | Missense Mutation (SNP) | VAF 38/500 reads (8%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.974); catalogued as COSV71676180; called by muse, mutect2
- FBN1 | c.4487C>T p.T1496M | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.054); catalogued as rs776199613; called by muse, mutect2, varscan2
- GM2A | c.388C>T p.R130C | Missense Mutation (SNP) | VAF 93/111 reads (84%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.603); catalogued as rs761084552; called by muse, mutect2, varscan2
- HIVEP2 | c.4294G>A p.V1432M | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.127); catalogued as rs920504937, COSV50077305; called by muse, mutect2, varscan2
- HMG20A | c.744G>C p.E248D | Missense Mutation (SNP) | VAF 28/67 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.857); catalogued as COSV100287742; called by muse, mutect2, varscan2
- ITGAX | c.2693C>G p.A898G | Missense Mutation (SNP) | VAF 12/100 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1301269329; called by muse, mutect2, varscan2
- KASH5 | c.124G>A p.E42K | Missense Mutation (SNP) | VAF 8/111 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as rs367728051; called by muse, mutect2
- KIAA0232 | c.890C>G p.S297* | Nonsense Mutation (SNP) | VAF 47/125 reads (38%) | catalogued as COSV56929710; called by muse, mutect2, varscan2
- KLHDC7A | c.2188C>T p.R730C | Missense Mutation (SNP) | VAF 3/31 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV101272883; called by muse, mutect2
- KSR2 | c.649G>A p.G217R | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT tolerated (0.4); PolyPhen benign (0.023); catalogued as rs1421037103, COSV60395845; called by muse, mutect2, varscan2
- MINAR1 | c.956C>T p.P319L | Missense Mutation (SNP) | VAF 90/223 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs984893553, COSV59583363, COSV59584062; called by muse, mutect2, varscan2
- MOGS | c.838C>T p.R280C | Missense Mutation (SNP) | VAF 21/60 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.828); catalogued as rs372551243; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MTUS2 | c.1108C>A p.H370N | Missense Mutation (SNP) | VAF 36/142 reads (25%) | SIFT tolerated (0.31); PolyPhen benign (0.108); catalogued as COSV70923418; called by muse, mutect2, varscan2
- NEK2 | c.1268G>A p.R423Q | Missense Mutation (SNP) | VAF 20/73 reads (27%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.685); catalogued as rs1211179624, COSV100878721, COSV65357583; called by muse, mutect2, varscan2
- NF1 | c.5357C>T p.S1786L (on ENST00000358273 / NM_001042492.3; = p.S1765L on NM_000267.3) | Missense Mutation (SNP) | VAF 45/119 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs1555533569, CS001442, COSV62198764, COSV62222750; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NPAP1 | c.1462G>A p.V488I | Missense Mutation (SNP) | VAF 175/404 reads (43%) | SIFT tolerated (0.54); PolyPhen benign (0.009); catalogued as rs1176202414, COSV100276390, COSV61508540; called by muse, mutect2, varscan2
- PARD3B | c.1579A>T p.I527F | Missense Mutation (SNP) | VAF 45/132 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV104414953; called by muse, mutect2, varscan2
- PCDHA9 | c.2141C>T p.T714M | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.29); catalogued as rs782210334, COSV65333304; called by muse, mutect2, varscan2
- PSMB8 | c.172G>T p.G58C (on ENST00000374882 / NM_148919.4; = p.G54C on NM_004159.5) | Missense Mutation (SNP) | VAF 23/74 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as COSV62754029; called by muse, mutect2, varscan2
- PUS3 | c.1446A>C p.*482Yext*2 | Nonstop Mutation (SNP) | VAF 30/82 reads (37%) | catalogued as COSV57105098; called by muse, mutect2
- RRBP1 | c.4099G>A p.A1367T (on ENST00000377813 / NM_001365613.2; = p.A934T on NM_004587.3) | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.437); catalogued as rs761671499, COSV55701320; called by muse, mutect2, varscan2
- RUNX1T1 | c.1412C>T p.A471V (on ENST00000265814 / NM_001198628.1; = p.A444V on NM_004349.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1462140811, COSV56138272; called by muse, mutect2, varscan2
- SALL1 | c.1492C>T p.R498C | Missense Mutation (SNP) | VAF 155/284 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs771745111, COSV51755534; called by muse, mutect2, varscan2
- SETD2 | c.5158G>A p.E1720K | Missense Mutation (SNP) | VAF 16/188 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as COSV57429791, COSV57447120; called by muse, mutect2
- SETX | c.5947G>C p.E1983Q | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV56380097; called by muse, mutect2, varscan2
- SLC30A1 | c.639_640del p.S214Wfs*2 | Frame Shift Del (DEL) | VAF 23/82 reads (28%) | catalogued as COSV65361648; called by mutect2, pindel, varscan2
- SOSTDC1 | c.73A>T p.K25* | Nonsense Mutation (SNP) | VAF 10/198 reads (5%) | catalogued as COSV61049074; called by muse, mutect2
- SRGAP3 | c.1217G>A p.R406Q | Missense Mutation (SNP) | VAF 58/127 reads (46%) | SIFT tolerated (0.53); PolyPhen probably damaging (0.968); catalogued as rs777305742, COSV64538017; called by muse, mutect2, varscan2
- TMEM225 | c.538G>A p.E180K | Missense Mutation (SNP) | VAF 27/82 reads (33%) | SIFT tolerated (0.38); PolyPhen benign (0.005); catalogued as rs77654932, COSV66693038; called by muse, mutect2, varscan2
- VPS52 | c.1010C>T p.S337L | Missense Mutation (SNP) | VAF 42/127 reads (33%) | SIFT tolerated (0.09); PolyPhen benign (0.175); catalogued as rs377130721; called by muse, mutect2, varscan2
- ZADH2 | c.1122C>G p.N374K | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT tolerated (0.2); PolyPhen benign (0.006); catalogued as COSV59269717; called by muse, mutect2, varscan2
- ZNF345 | c.245G>A p.R82Q | Missense Mutation (SNP) | VAF 150/248 reads (60%) | SIFT deleterious (0.04); PolyPhen benign (0.059); catalogued as rs143253432; called by muse, mutect2, varscan2
- ZNF512B | c.253C>T p.R85* | Nonsense Mutation (SNP) | VAF 12/23 reads (52%) | catalogued as COSV53871020; called by muse, mutect2, varscan2
- ZNF701 | c.1007A>G p.Y336C (on ENST00000301093; = p.Y270C on NM_018260.3) | Missense Mutation (SNP) | VAF 24/218 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV56527443; called by muse, mutect2, varscan2
- ADCY1 | c.1018A>C p.T340P | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.953); called by muse, mutect2
- ANKRD17 | c.2119G>A p.G707S | Missense Mutation (SNP) | VAF 63/184 reads (34%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- APLF | c.584T>G p.L195* | Nonsense Mutation (SNP) | VAF 82/189 reads (43%) | called by muse, mutect2, varscan2
- BBS2 | c.415G>A p.G139S | Missense Mutation (SNP) | VAF 26/168 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- BTBD8 | c.958C>A p.L320I | Missense Mutation (SNP) | VAF 61/130 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- CAPZB | c.261del p.M88Cfs*6 | Frame Shift Del (DEL) | VAF 21/67 reads (31%) | called by mutect2, pindel, varscan2
- CDCA5 | c.679-2A>G p.X227_splice | Splice Site (SNP) | VAF 12/27 reads (44%) | called by muse, mutect2, varscan2
- CHD6 | c.4302G>C p.R1434S | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- DAXX | c.944A>T p.D315V | Missense Mutation (SNP) | VAF 26/90 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- DPPA4 | c.157dup p.M53Nfs*7 | Frame Shift Ins (INS) | VAF 100/243 reads (41%) | called by mutect2, pindel, varscan2
- ECM2 | c.491C>A p.S164Y | Missense Mutation (SNP) | VAF 30/111 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.372); called by muse, mutect2, varscan2
- EP400 | c.3029G>A p.R1010K | Missense Mutation (SNP) | VAF 38/70 reads (54%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.57); called by muse, mutect2, varscan2
- FAT4 | c.8797C>A p.Q2933K | Missense Mutation (SNP) | VAF 48/95 reads (51%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- ITGBL1 | c.541G>C p.D181H | Missense Mutation (SNP) | VAF 16/614 reads (3%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); called by muse, mutect2
- JADE3 | c.2058G>A p.M686I | Missense Mutation (SNP) | VAF 47/101 reads (47%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- KIAA1586 | c.721A>G p.K241E | Missense Mutation (SNP) | VAF 49/119 reads (41%) | SIFT tolerated (0.22); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- LRCH2 | c.1026T>A p.N342K | Missense Mutation (SNP) | VAF 23/57 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.257); called by muse, mutect2, varscan2
- ME3 | c.1364G>T p.C455F | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); called by muse, mutect2, varscan2
- METTL25 | c.1259A>C p.E420A | Missense Mutation (SNP) | VAF 34/145 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.559); called by muse, mutect2, varscan2
- MYH2 | c.2811G>T p.E937D | Missense Mutation (SNP) | VAF 98/278 reads (35%) | SIFT tolerated (0.05); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- NVL | c.2408G>A p.C803Y | Missense Mutation (SNP) | VAF 31/132 reads (23%) | SIFT tolerated (0.97); PolyPhen benign (0.389); called by muse, mutect2, varscan2
- ORAI2 | c.410C>T p.S137F | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- PLEKHG1 | c.3757A>T p.R1253* | Nonsense Mutation (SNP) | VAF 71/249 reads (29%) | called by muse, mutect2, varscan2
- RNF130 | c.1246G>T p.V416L | Missense Mutation (SNP) | VAF 26/71 reads (37%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0); called by muse, mutect2, varscan2
- ROCK1 | c.3172G>T p.E1058* | Nonsense Mutation (SNP) | VAF 108/562 reads (19%) | called by muse, mutect2, varscan2
- SLCO5A1 | c.1789A>C p.N597H | Missense Mutation (SNP) | VAF 61/161 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- SNAPIN | c.317dup p.R107Efs*57 | Frame Shift Ins (INS) | VAF 22/99 reads (22%) | called by mutect2, pindel, varscan2
- SRPRB | c.464T>G p.V155G | Missense Mutation (SNP) | VAF 69/177 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SUGP2 | c.919C>T p.L307F | Missense Mutation (SNP) | VAF 4/78 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0); called by muse, mutect2
- SYNE1 | c.13650C>A p.C4550* (on ENST00000367255 / NM_182961.4; = p.C4479* on NM_033071.3) | Nonsense Mutation (SNP) | VAF 70/292 reads (24%) | called by muse, mutect2, varscan2
- SZT2 | c.8578G>T p.A2860S (on ENST00000634258 / NM_001365999.1; = p.A2803S on NM_015284.4) | Missense Mutation (SNP) | VAF 12/77 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- TAS2R10 | c.205A>G p.I69V | Missense Mutation (SNP) | VAF 67/203 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- TMEM117 | c.863A>G p.K288R | Missense Mutation (SNP) | VAF 79/218 reads (36%) | SIFT tolerated (0.67); PolyPhen benign (0); called by muse, mutect2, varscan2
- WDFY3 | c.6424A>T p.S2142C | Missense Mutation (SNP) | VAF 34/99 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.321); called by muse, mutect2, varscan2
- ZNF658 | c.43G>T p.V15L | Missense Mutation (SNP) | VAF 36/128 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.939); called by muse, mutect2, varscan2
- ANTXR1 | c.1314T>G p.R438= | Silent (SNP) | VAF 89/256 reads (35%) | catalogued as COSV58022560; called by muse, mutect2, varscan2
- ARHGAP35 | c.4017C>A p.I1339= | Silent (SNP) | VAF 42/84 reads (50%) | catalogued as rs764279682, COSV68332988; called by muse, mutect2, varscan2
- AVPR1A | c.1059C>A p.G353= | Silent (SNP) | VAF 63/227 reads (28%) | catalogued as COSV54548188; called by muse, mutect2, varscan2
- BMPR1B | c.243T>C p.C81= | Silent (SNP) | VAF 138/373 reads (37%) | catalogued as COSV52782268; called by muse, mutect2, varscan2
- CALHM2 | c.75C>T p.N25= | Silent (SNP) | VAF 11/36 reads (31%) | catalogued as rs151104032; called by muse, mutect2, varscan2
- CNTNAP4 | c.3867G>A p.L1289= | Silent (SNP) | VAF 34/114 reads (30%) | catalogued as COSV56702203; called by muse, mutect2, varscan2
- COG1 | c.1743C>T p.I581= | Silent (SNP) | VAF 27/56 reads (48%) | catalogued as rs1336351335, COSV55429079; called by muse, mutect2, varscan2
- CPAMD8 | c.1614G>C p.R538= (on ENST00000651564; = p.R491= on NM_015692.5) | Silent (SNP) | VAF 6/27 reads (22%) | catalogued as COSV52240612; called by muse, mutect2, varscan2
- CPLX2 | c.90G>A p.A30= | Silent (SNP) | VAF 16/21 reads (76%) | catalogued as rs1342150504; called by muse, mutect2, varscan2
- CST2 | c.255C>T p.F85= | Silent (SNP) | VAF 83/149 reads (56%) | catalogued as rs201981599, COSV59031283; called by muse, mutect2, varscan2
- DYM | c.1995C>G p.T665= | Silent (SNP) | VAF 75/199 reads (38%) | called by muse, mutect2, varscan2
- EVC2 | c.936G>T p.L312= | Silent (SNP) | VAF 14/77 reads (18%) | called by muse, mutect2, varscan2
- GLG1 | c.2649C>T p.V883= | Silent (SNP) | VAF 122/206 reads (59%) | catalogued as COSV52675057; called by muse, mutect2, varscan2
- IGSF11 | c.1170C>A p.G390= (on ENST00000393775 / NM_001015887.3; = p.G389= on NM_152538.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 88/208 reads (42%) | catalogued as COSV61179257; called by muse, mutect2, varscan2
- KCNQ3 | c.2526G>A p.T842= | Silent (SNP) | VAF 16/32 reads (50%) | catalogued as rs749906898, COSV66466837; called by muse, mutect2, varscan2
- MYPN | c.3300G>A p.P1100= | Silent (SNP) | VAF 48/128 reads (38%) | catalogued as rs777293049, COSV62740239; ClinVar: likely benign; called by muse, mutect2, varscan2
- NAB2 | c.675G>C p.L225= | Silent (SNP) | VAF 7/28 reads (25%) | catalogued as COSV55668161; called by muse, mutect2
- OR5AN1 | c.48G>T p.L16= | Silent (SNP) | VAF 109/276 reads (39%) | catalogued as COSV58322949; called by muse, mutect2, varscan2
- PCDHGB5 | c.1353G>A p.A451= | Silent (SNP) | VAF 19/58 reads (33%) | catalogued as COSV53975217; called by muse, mutect2, varscan2
- PCDHGC4 | c.561C>T p.D187= | Silent (SNP) | VAF 42/100 reads (42%) | called by muse, mutect2, varscan2
- TRHDE | c.3036C>T p.D1012= | Silent (SNP) | VAF 9/61 reads (15%) | catalogued as rs200307970, COSV53867883; called by muse, mutect2, varscan2
- ZNF449 | c.123A>T p.A41= | Silent (SNP) | VAF 64/136 reads (47%) | called by muse, mutect2, varscan2
- AC005863.1 | n.190G>A | RNA (SNP) | VAF 41/73 reads (56%) | catalogued as rs759590948; called by muse, mutect2, varscan2
- POLQ | chr3:121546520 G>A | 5'Flank (SNP) | VAF 50/111 reads (45%) | called by muse, mutect2, varscan2
- PUS3 | c.*2C>A | 3'UTR (SNP) | VAF 28/77 reads (36%) | called by muse, mutect2
- RIMS2 | c.1692+269T>G | Intron (SNP) | VAF 42/95 reads (44%) | catalogued as COSV51727556; called by muse, mutect2, varscan2
- TMPRSS2 | c.*1T>A | 3'UTR (SNP) | VAF 9/27 reads (33%) | called by muse, mutect2, varscan2
